Gene-level copy-number profile of tumor specimen TCGA-HS-A5N7-01A from TCGA case TCGA-HS-A5N7, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 67.8 years (24,775 days).
Specimen TCGA-HS-A5N7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.101124bf-4d90-4f06-8c7d-06181e981d24.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HS-A5N7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/71a0bbb1-8f3f-428a-92a7-7bcbd3f30955

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 14,832; copy number 2: 42,888; copy number 3: 1,708; copy number 4: 371.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HS-A5N7-01A-21D-A26F-01): tumor purity 0.82, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–206,392, 4 genes: AL035696.2, AL035696.3, AL035696.4, AL035696.1.
- chr10:87,591,607–87,971,930, 12 genes: AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3.
- chr17:82,519,713–82,644,662, 5 genes (within-gene range 0–1): FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 14,832. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
